Somatic mutation profile of tumor specimen TCGA-EE-A2GB-06A (aliquot TCGA-EE-A2GB-06A-11D-A197-08) from TCGA case TCGA-EE-A2GB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 52.4 years (19,124 days).
Specimen TCGA-EE-A2GB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50f3bc9c-a94c-4042-b940-b59fb02c7aa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GB-10A (Blood Derived Normal), aliquot TCGA-EE-A2GB-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8405896-d462-4cb4-ad93-5cff4129a193

The open-access MAF lists 783 somatic variants for this specimen: 522 protein-altering or splice-affecting, 250 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 479, Silent 250, Nonsense Mutation 24, Splice Site 8, Intron 8, Splice Region 7, RNA 3, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1.

Variants (750 of 783; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV51512596; called by muse, mutect2, varscan2
- TP63 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761885185, COSV53196562, COSV53210463; called by muse, mutect2, varscan2
- A2M | c.1894G>A p.G632R | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59387443; called by muse, mutect2, varscan2
- A2M | c.273C>T p.V91= | Splice Region (SNP) | VAF 7/51 reads (14%) | catalogued as rs779039949, COSV59387457; called by muse, mutect2
- A2M | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs746195619, COSV59383506; called by muse, mutect2, varscan2
- ABCA13 | c.3418A>C p.K1140Q | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV70030328; called by muse, mutect2, varscan2
- ABCB8 | c.857C>T p.S286F (on ENST00000297504 / NM_001282291.2; = p.S269F on NM_007188.5) | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52505217; called by muse, mutect2, varscan2
- ABCC10 | c.781C>T p.R261C (on ENST00000372530 / NM_001198934.2; = p.R218C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs868482897, COSV55087397; called by muse, mutect2, varscan2
- AC018630.4 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs563409901, COSV57392251; called by muse, mutect2, varscan2
- ACOT11 | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59348849; called by muse, mutect2, varscan2
- ACP2 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99922109; called by muse, mutect2, varscan2
- ACP2 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772500466, COSV99922111; called by muse, mutect2, varscan2
- ACP7 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58699476; called by muse, mutect2, varscan2
- ADAM18 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV55843435; called by muse, mutect2, varscan2
- ADAM18 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV55843802; called by muse, mutect2, varscan2
- ADAM29 | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV63664072, COSV63665343; called by muse, varscan2
- ADAM7 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.955); catalogued as COSV51540706, COSV99443312; called by muse, varscan2
- ADAMTS10 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV54355342; called by muse, mutect2, varscan2
- ADAMTS2 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs867353605, COSV52377133; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as rs1364350906, COSV54445135; called by muse, mutect2, varscan2
- ADGRA2 | c.2594C>T p.T865I | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs772301014, COSV55104016; called by muse, mutect2, varscan2
- ADGRF3 | c.491G>A p.R164K (on ENST00000311519 / NM_001145168.1; = p.R105K on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV61050629; called by muse, mutect2, varscan2
- ADGRF5 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV51934531; called by muse, mutect2, varscan2
- ADGRL1 | c.547C>T p.R183C (on ENST00000340736 / NM_001008701.3; = p.R178C on NM_014921.5) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369670781; called by muse, mutect2
- ADGRL2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54669277; called by muse, mutect2, varscan2
- ADGRL4 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV66060039; called by muse, mutect2, varscan2
- ADH1C | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 217/492 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV72463418; called by muse, mutect2, varscan2
- AFF4 | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as COSV54795258; called by muse, mutect2, varscan2
- AGXT2 | c.861A>C p.E287D | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51486928; called by muse, mutect2, varscan2
- ALG5 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV53505610; called by muse, mutect2, varscan2
- AMER3 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV58466554; called by muse, mutect2, varscan2
- ANAPC1 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs750827131, COSV61976375; called by muse, mutect2, varscan2
- ANKAR | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV55613295; called by muse, mutect2, varscan2
- ANKEF1 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1440335644, COSV65692535; called by muse, mutect2, varscan2
- ANKRD22 | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 76/97 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as COSV64236676; called by muse, mutect2, varscan2
- ANKRD30A | c.2578G>A p.A860T (on ENST00000611781; = p.A804T on NM_052997.2) | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs771766272, COSV64605649; called by muse, mutect2, varscan2
- AP002512.3 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs202085886, COSV54406984; called by muse, mutect2, varscan2
- APBB1IP | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.16); catalogued as COSV66132816; called by muse, mutect2, varscan2
- APOB | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 130/486 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51937617; called by muse, mutect2, varscan2
- APPL2 | c.1931A>G p.N644S | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV51590847; called by muse, mutect2, varscan2
- ARGFX | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57682438; called by muse, varscan2
- ARHGAP22 | c.2045C>T p.S682L | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs375289109; called by muse, mutect2, varscan2
- ARHGAP22 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV50946139; called by muse, mutect2, varscan2
- ARHGAP30 | c.2231A>G p.D744G | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.284); catalogued as COSV63516845; called by muse, mutect2, varscan2
- ARHGAP44 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52394869; called by muse, mutect2, varscan2
- ARHGEF7 | c.2313T>C p.R771= (on ENST00000646102 / NM_001354046.1; = p.S555= on NM_003899.5 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 54/148 reads (36%) | catalogued as COSV54544141; called by muse, mutect2, varscan2
- ARSJ | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1310436940, COSV59538058; called by muse, mutect2, varscan2
- ATG5 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58348119; called by muse, mutect2, varscan2
- ATP13A2 | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as rs1419194128, COSV58700930; called by muse, mutect2, varscan2
- ATXN1 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55213063; called by muse, mutect2, varscan2
- BBOX1 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs753618329, COSV54190734, COSV99589443; called by muse, mutect2, varscan2
- BCL2L15 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as rs774688441, COSV63643030; called by muse, mutect2, varscan2
- BCL9L | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV52684815; called by muse, mutect2, varscan2
- BMP15 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 57/63 reads (90%) | SIFT tolerated (0.42); PolyPhen benign (0.094); catalogued as COSV53140670; called by muse, mutect2, varscan2
- BNIP5 | c.1735G>A p.V579I | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV101465112; called by muse, mutect2, varscan2
- BRSK2 | c.587A>G p.K196R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100372357; called by muse, varscan2
- BSN | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1464430484, COSV56513974, COSV99609977; called by muse, mutect2, varscan2
- BTBD9 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as rs1486894965, COSV58426963; called by muse, varscan2
- BTN2A2 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs750636124, COSV61857585; called by muse, mutect2, varscan2
- C11orf58 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV57178619; called by muse, mutect2, varscan2
- C12orf56 | c.1512A>T p.G504= (on ENST00000543942 / NM_001170633.2; = p.G344= on NM_001099676.3) | Splice Region (SNP) | VAF 30/97 reads (31%) | catalogued as COSV100399029; called by muse, mutect2, varscan2
- C12orf56 | c.1511G>A p.G504E (on ENST00000543942 / NM_001170633.2; = p.G344E on NM_001099676.3) | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753165036, COSV100399031; called by muse, mutect2, varscan2
- C1R | c.485C>T p.S162F (on ENST00000536053 / NM_001354346.2; = p.S148F on NM_001733.7) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV56925339; called by muse, mutect2, varscan2
- C20orf194 | c.2018+2T>A p.X673_splice | Splice Site (SNP) | VAF 54/270 reads (20%) | catalogued as COSV52696611; called by muse, mutect2, varscan2
- C2CD5 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61724863; called by muse, mutect2, varscan2
- C3 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771305132, COSV55573413; called by muse, mutect2, varscan2
- C4BPA | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs141825051; called by muse, mutect2, varscan2
- C6 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs867408360, COSV54706337; called by muse, mutect2, varscan2
- C9orf64 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59032614; called by muse, mutect2, varscan2
- CA1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV56278787; called by muse, mutect2, varscan2
- CA12 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs1462607562, COSV51606015; called by muse, mutect2, varscan2
- CACNA2D3 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.101); catalogued as rs865798465, COSV55540495; called by muse, mutect2, varscan2
- CADM2 | c.416G>A p.G139D (on ENST00000407528 / NM_001167674.2; = p.G141D on NM_153184.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.413); catalogued as COSV67378182; called by muse, mutect2, varscan2
- CADM2 | c.592G>A p.G198R (on ENST00000407528 / NM_001167674.2; = p.G200R on NM_153184.4) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67359023, COSV67362296; called by muse, mutect2, varscan2
- CALCR | c.317-1G>A p.X106_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | catalogued as COSV64007459; called by muse, mutect2, varscan2
- CALN1 | c.424C>T p.H142Y (on ENST00000329008 / NM_001017440.3; = p.H184Y on NM_031468.4) | Missense Mutation (SNP) | VAF 67/110 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs866127298, COSV61131410; called by muse, mutect2, varscan2
- CAMTA2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs780497614, COSV61835332; called by muse, mutect2, varscan2
- CAPN15 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771135104, COSV99562174; called by muse, varscan2
- CCDC146 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 72/122 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV53549163; called by muse, mutect2, varscan2
- CCDC59 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV50259297; called by muse, mutect2, varscan2
- CCDC62 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV53434000; called by muse, mutect2, varscan2
- CCDC87 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV59579228; called by muse, mutect2, varscan2
- CCDC88C | c.5893G>A p.G1965R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs1188669450, COSV57796826; called by muse, varscan2
- CCT8L2 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.604); catalogued as COSV63462616; called by muse, mutect2, varscan2
- CD226 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.426); catalogued as COSV54612605; called by muse, mutect2, varscan2
- CDCA2 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs750926009, COSV57945810; called by mutect2, varscan2
- CDHR3 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs757473628, COSV58417680; called by muse, mutect2, varscan2
- CDK18 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.614); catalogued as COSV63727646; called by muse, varscan2
- CEACAM5 | c.1999T>C p.S667P | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV55752436; called by muse, mutect2, varscan2
- CEL | c.688C>T p.P230S (on ENST00000673714; = p.P227S on NM_001807.6) | Missense Mutation (SNP) | VAF 66/85 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60827593; called by muse, varscan2
- CEMIP2 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV65487494; called by muse, mutect2, varscan2
- CENPE | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54382015; called by muse, mutect2, varscan2
- CFAP57 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV65264545; called by muse, mutect2, varscan2
- CFHR4 | c.76C>T p.P26S (on ENST00000367416 / NM_001201551.2; = p.P27S on NM_006684.5) | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV52226937, COSV52229560; called by muse, mutect2, varscan2
- CHD2 | c.5224C>T p.R1742* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV67710577; called by muse, mutect2, varscan2
- CHRDL1 | c.431G>A p.G144E (on ENST00000372045; = p.G150E on NM_145234.4) | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs867635832, COSV54325570; called by muse, mutect2, varscan2
- CHRNA4 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as COSV64717697; called by muse, mutect2, varscan2
- CLEC10A | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1013332163, COSV54701168; called by muse, mutect2, varscan2
- CLIP4 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV60749454; called by muse, mutect2, varscan2
- CNGA2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV61704623; called by muse, mutect2, varscan2
- CNTNAP4 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777332448, COSV56682926; called by muse, mutect2, varscan2
- COL16A1 | c.1564G>A p.G522R | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54706845; called by muse, mutect2, varscan2
- COL17A1 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs772686862, COSV62227042; called by muse, varscan2
- COL5A1 | c.4030C>T p.P1344S | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65667841; called by muse, mutect2, varscan2
- COL6A3 | c.6329G>A p.G2110E | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55079933, COSV55091796; called by muse, mutect2, varscan2
- COPB2 | c.916A>G p.M306V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1449027670, COSV60812740; called by muse, mutect2, varscan2
- CPED1 | c.2851G>A p.G951R | Missense Mutation (SNP) | VAF 68/107 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60003434; called by muse, mutect2, varscan2
- CPNE4 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1330733089, COSV70192470; called by muse, mutect2
- CPXCR1 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs761800452, COSV52162582; called by muse, mutect2, varscan2
- CRNKL1 | c.1445A>G p.E482G | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV66105980; called by muse, mutect2, varscan2
- CRYBB2 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68005520; called by muse, varscan2
- CRYBG2 | c.3151C>T p.P1051S | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as COSV100366313; called by muse, mutect2, varscan2
- CSE1L | c.2233C>T p.H745Y | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53702242; called by muse, mutect2, varscan2
- CSMD1 | c.1889T>G p.F630C (on ENST00000520002; = p.F629C on NM_033225.6) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59330699; called by muse, varscan2
- CSMD3 | c.8057C>A p.T2686N (on ENST00000297405 / NM_001363185.1; = p.T2582N on NM_052900.3) | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); catalogued as COSV99825552; called by muse, mutect2, varscan2
- CSMD3 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV52194681, COSV52324654; called by muse, mutect2, varscan2
- CSRNP1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV56188229; called by muse, mutect2, varscan2
- CUX2 | c.3605C>T p.S1202F | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55634148; called by muse, mutect2, varscan2
- DDX20 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV63779358; called by muse, mutect2, varscan2
- DDX46 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV62799493; called by muse, mutect2, varscan2
- DDX60 | c.4343C>T p.S1448F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV67096975; called by muse, mutect2
- DEFB116 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs976484149, COSV101269248, COSV68722154; called by muse, mutect2, varscan2
- DIS3L2 | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99805533; called by muse, mutect2
- DMKN | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.077); catalogued as COSV60086674; called by muse, mutect2
- DNAH1 | c.12308G>A p.W4103* | Nonsense Mutation (SNP) | VAF 117/208 reads (56%) | catalogued as COSV56234964; called by muse, mutect2, varscan2
- DNAH10 | c.12452G>A p.G4151E (on ENST00000409039; = p.G4090E on NM_207437.3) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69002296; called by muse, mutect2, varscan2
- DNAH3 | c.11272G>A p.E3758K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as rs868191973, COSV54510062; called by muse, mutect2, varscan2
- DNAH5 | c.6511G>A p.A2171T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV54228540; called by muse, mutect2, varscan2
- DNAH7 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs372668189; called by muse, mutect2, varscan2
- DNAH8 | c.7577A>T p.N2526I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59450339; called by muse, mutect2, varscan2
- DNAH8 | c.11260G>A p.E3754K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs267601020, COSV59439459; called by muse, mutect2, varscan2
- DNTTIP2 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63284088; called by muse, varscan2
- DOK5 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs765612921, COSV52817152; called by muse, mutect2, varscan2
- DPEP1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs139832614; called by muse, mutect2, varscan2
- DPYD | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs377169736, COSV60078822, COSV60082730; called by muse, mutect2, varscan2
- DPYSL4 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58307708, COSV58308721; called by muse, mutect2, varscan2
- DSG4 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV57392377; called by muse, mutect2, varscan2
- DYRK2 | c.350C>G p.T117R (on ENST00000344096 / NM_006482.3; = p.T44R on NM_003583.4) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV59846319; called by muse, mutect2, varscan2
- DYSF | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV50386101, COSV50531125; called by muse, mutect2
- DZIP3 | c.1160A>T p.K387M | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV64312238; called by muse, mutect2, varscan2
- ECI1 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as COSV57039288; called by muse, mutect2, varscan2
- EHMT2 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 142/296 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1249501243, COSV64996189; called by muse, mutect2, varscan2
- EIF3B | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1418263620, COSV62803222; called by muse, mutect2, varscan2
- ELMO1 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs1447676557, COSV60297074; called by muse, mutect2, varscan2
- ENO3 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 64/107 reads (60%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV52777743; called by muse, mutect2, varscan2
- EPHB3 | c.2777C>T p.T926I | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.825); catalogued as rs143430250, COSV57806333; called by muse, mutect2, varscan2
- ERCC6L | c.3443G>A p.G1148E | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1356985455, COSV100559001; called by muse, mutect2
- ERICH6 | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 65/113 reads (58%) | catalogued as COSV55800853; called by muse, mutect2, varscan2
- ETV1 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV54143547; called by muse, mutect2, varscan2
- ETV6 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV67150396; called by muse, mutect2, varscan2
- F13B | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66374083; called by muse, mutect2, varscan2
- FAM193A | c.2113A>C p.T705P | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.387); catalogued as COSV61194535; called by muse, mutect2, varscan2
- FAM193A | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs1247023676, COSV61194543; called by muse, mutect2, varscan2
- FAM47C | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.953); catalogued as COSV63726901, COSV63726978, COSV63727843; called by muse, mutect2, varscan2
- FAM53C | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as COSV53511734; called by muse, mutect2, varscan2
- FAM83B | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs868381299, COSV60922538; called by muse, varscan2
- FAM83B | c.2660C>A p.P887Q | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60922543; called by muse, varscan2
- FAM90A1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.933); catalogued as COSV56712216; called by muse, mutect2, varscan2
- FAT2 | c.7963C>T p.Q2655* | Nonsense Mutation (SNP) | VAF 40/73 reads (55%) | catalogued as COSV55820677, COSV55822593; called by muse, mutect2, varscan2
- FAT3 | c.9088G>A p.D3030N | Missense Mutation (SNP) | VAF 157/198 reads (79%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV53118121; called by muse, varscan2
- FAT3 | c.10129C>T p.H3377Y | Missense Mutation (SNP) | VAF 219/286 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1162807333, COSV53118144; called by muse, mutect2, varscan2
- FBXW10 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1244074733, COSV57317914; called by muse, mutect2, varscan2
- FCRL1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as rs772311289, COSV63825465; called by muse, mutect2, varscan2
- FGGY | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58034159; called by muse, mutect2, varscan2
- FLG | c.11672C>T p.S3891F | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs775340348, COSV64242546; called by muse, mutect2, varscan2
- FLG2 | c.6017G>A p.R2006K | Missense Mutation (SNP) | VAF 153/418 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV101165923, COSV66169124; called by muse, mutect2, varscan2
- FNDC3B | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV61042968; called by muse, mutect2, varscan2
- FOXK2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV58879381; called by muse, mutect2, varscan2
- FSHB | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV54221887; called by muse, mutect2, varscan2
- GABRA2 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62915135; called by muse, mutect2, varscan2
- GNA15 | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV53586306; called by muse, mutect2, varscan2
- GNGT2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV55929976; called by muse, mutect2, varscan2
- GPR171 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.992); catalogued as COSV56380632, COSV56390982; called by muse, mutect2, varscan2
- GPRIN2 | c.998A>G p.Q333R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.136); catalogued as COSV65401132; called by muse, mutect2
- GRHL2 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52549020; called by muse, mutect2, varscan2
- GRIN2A | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs267604688, COSV58032774; called by muse, mutect2, varscan2
- GRM8 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs780568800, COSV58821868; called by muse, mutect2, varscan2
- GTF3C1 | c.4621C>T p.R1541C | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as rs918573439, COSV62239512; called by muse, mutect2, varscan2
- HAS1 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV99708220; called by muse, mutect2
- HAS3 | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.615); catalogued as COSV54707205; called by muse, mutect2, varscan2
- HCN4 | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 31/44 reads (70%) | catalogued as COSV56083985; called by muse, varscan2
- HECTD4 | c.11227C>T p.P3743S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1271924341, COSV66392813; called by muse, mutect2, varscan2
- HECW2 | c.2306G>A p.G769E | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.538); catalogued as COSV53661151; called by muse, mutect2, varscan2
- HECW2 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53661164; called by muse, mutect2, varscan2
- HGD | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV52198461; called by muse, mutect2, varscan2
- HIF3A | c.1883C>T p.T628I (on ENST00000377670 / NM_152795.4; = p.T559I on NM_022462.4) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.052); catalogued as COSV52199114; called by muse, mutect2, varscan2
- HRG | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV51645941; called by muse, mutect2, varscan2
- HRNR | c.3260C>T p.S1087L | Missense Mutation (SNP) | VAF 187/692 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs547893856, COSV64258766, COSV64261974; called by muse, varscan2
- HS3ST4 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as COSV58816853; called by muse, mutect2, varscan2
- HS6ST3 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV65009491; called by muse, mutect2, varscan2
- HSP90AB1 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62334745; called by muse, mutect2, varscan2
- HSPH1 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 109/244 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as COSV60711686; called by muse, mutect2, varscan2
- HUS1 | c.340A>T p.T114S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV51839573; called by muse, mutect2, varscan2
- HVCN1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.411); catalogued as COSV54372338; called by muse, mutect2, varscan2
- HYDIN | c.4351C>T p.Q1451* | Nonsense Mutation (SNP) | VAF 55/115 reads (48%) | catalogued as COSV66832417; called by muse, mutect2, varscan2
- HYDIN | c.3765G>A p.M1255I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV66831088; called by mutect2, varscan2
- IFNA21 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 103/134 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.407); catalogued as rs754004149, COSV66518485, COSV66519113; called by muse, mutect2, varscan2
- IGLL1 | c.230G>A p.W77* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as rs759328026, COSV50769970; called by muse, mutect2, varscan2
- IGSF21 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474340067, COSV52132771; called by muse, varscan2
- IL10RA | c.1334G>A p.G445D | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs946800288, COSV57140825; called by muse, mutect2, varscan2
- IL1RL1 | c.970A>C p.I324L (on ENST00000233954 / NM_016232.5; = p.S324R on NM_003856.4) | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV52116420; called by muse, mutect2, varscan2
- IL2RA | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV56921057; called by muse, mutect2, varscan2
- ILDR1 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV56550346; called by muse, mutect2, varscan2
- IMPG1 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as COSV64058379; called by muse, mutect2, varscan2
- INHBE | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 32/103 reads (31%) | catalogued as rs1440312005, COSV56988251; called by muse, varscan2
- INPP5D | c.2854C>T p.P952S (on ENST00000445964 / NM_001017915.3; = p.P951S on NM_005541.5) | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64037454; called by muse, mutect2, varscan2
- INPPL1 | c.2248T>C p.F750L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV53356026; called by muse, mutect2, varscan2
- ITGA4 | c.2158C>T p.H720Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); catalogued as COSV67897531; called by muse, mutect2
- JAKMIP3 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs768594690, COSV53823807; called by muse, mutect2, varscan2
- KALRN | c.7579G>A p.D2527N (on ENST00000360013 / NM_001024660.4; = p.D830N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV52257435; called by muse, mutect2, varscan2
- KCMF1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101301228; called by muse, mutect2, varscan2
- KCNH2 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100059187, COSV51136478; called by muse, mutect2, varscan2
- KCNN2 | c.446T>C p.M149T (on ENST00000264773; = p.M361T on NM_021614.4) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53289614; called by muse, mutect2, varscan2
- KCNS3 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58407108; called by muse, mutect2, varscan2
- KCNU1 | c.3320G>A p.W1107* | Nonsense Mutation (SNP) | VAF 53/156 reads (34%) | catalogued as COSV67756446; called by muse, mutect2, varscan2
- KDM2B | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100997206; called by muse, mutect2, varscan2
- KIAA1217 | c.2950G>A p.G984R | Missense Mutation (SNP) | VAF 71/90 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551093199, COSV56817382; called by muse, mutect2, varscan2
- KIF5A | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV99672467; called by muse, mutect2, varscan2
- KL | c.1576G>A p.G526R | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759516810, COSV66308911; called by muse, mutect2, varscan2
- KLHDC7A | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); catalogued as rs1380586041, COSV68769907; called by muse, mutect2, varscan2
- KRT32 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.304); catalogued as rs147094229; called by muse, mutect2, varscan2
- KRT79 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760206986, COSV57938662, COSV57940344; called by muse, mutect2, varscan2
- KRTAP4-4 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV66811239; called by muse, mutect2, varscan2
- LAMA3 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV58069738; called by muse, mutect2, varscan2
- LAMA5 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV53361094; called by muse, mutect2
- LAMB4 | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs752569124, COSV52720535; called by muse, mutect2, varscan2
- LILRA5 | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs267605665, COSV56642926; called by mutect2, varscan2
- LMAN2 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57424732; called by muse, mutect2, varscan2
- LPAR3 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV65453746; called by muse, mutect2, varscan2
- LPGAT1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65351693; called by muse, mutect2, varscan2
- LRP1B | c.4909G>A p.G1637R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755279123, COSV67184570; called by muse, mutect2, varscan2
- LRTM1 | c.241T>G p.L81V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55543458, COSV99836158; called by muse, mutect2, varscan2
- LUM | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV57127963; called by muse, mutect2, varscan2
- LY75 | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.153); catalogued as COSV55106483; called by muse, mutect2
- LY9 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.148); catalogued as rs376341054; called by muse, mutect2, varscan2
- MAGI3 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV56836584; called by muse, mutect2, varscan2
- MAP3K21 | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV64044944; called by muse, mutect2, varscan2
- MAP3K4 | c.3757C>T p.P1253S | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62335393; called by muse, mutect2, varscan2
- MAP3K4 | c.3758C>T p.P1253L | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs200731463, COSV100815057, COSV62336244; called by muse, mutect2, varscan2
- MBD5 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV68697262; called by muse, mutect2, varscan2
- MC5R | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61254799; called by muse, mutect2, varscan2
- MDN1 | c.9458C>T p.S3153F | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV65522511; called by muse, mutect2, varscan2
- MED12 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as rs761157306, COSV61341478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MED25 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV57204917; called by muse, mutect2, varscan2
- MERTK | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54929913; called by muse, mutect2, varscan2
- MGAM | c.1880G>A p.G627E | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72074020; called by muse, mutect2, varscan2
- MGAM | c.3319G>A p.D1107N | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.949); catalogued as COSV72074751; called by muse, mutect2, varscan2
- MGAT4A | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV53847541; called by muse, mutect2, varscan2
- MKNK1 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs773183942, COSV57861431; called by muse, mutect2, varscan2
- MKRN2 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV50105293; called by muse, mutect2, varscan2
- MTRF1 | c.1163A>T p.Y388F | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV65263370; called by muse, mutect2, varscan2
- MUC16 | c.39433G>C p.V13145L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.139); catalogued as COSV66692540; called by muse, mutect2, varscan2
- MUC16 | c.25661C>T p.S8554F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV67469567; called by muse, mutect2, varscan2
- MUC16 | c.6250A>G p.S2084G | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67449432, COSV67469580; called by muse, mutect2, varscan2
- MUC17 | c.4307C>T p.S1436F | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV60290074; called by muse, mutect2, varscan2
- MUSK | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs773818596, COSV51878062; called by muse, mutect2, varscan2
- MXRA5 | c.5952G>A p.W1984* | Nonsense Mutation (SNP) | VAF 29/35 reads (83%) | catalogued as COSV54237216; called by muse, mutect2, varscan2
- MYBPC3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV57028302; called by muse, mutect2, varscan2
- MYH15 | c.4424C>T p.S1475F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.278); catalogued as COSV56311229; called by muse, mutect2, varscan2
- MYH7B | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV53420654; called by muse, mutect2, varscan2
- MYLK3 | c.2163G>A p.M721I | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV67364516; called by muse, mutect2, varscan2
- MYO15A | c.8737C>T p.R2913C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1417964003, COSV52757831; called by muse, varscan2
- MYO18B | c.7024G>A p.E2342K | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.062); catalogued as rs370531504; called by muse, mutect2, varscan2
- MYO19 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1381642926; called by muse, mutect2, varscan2
- MYO5B | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53220051; called by muse, mutect2, varscan2
- MYO9B | c.3511G>T p.E1171* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV101261302; called by muse, mutect2, varscan2
- MYOC | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM005518, COSV50675187; called by muse, mutect2, varscan2
- NCK2 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51891750; called by muse, mutect2, varscan2
- NCOA6 | c.2851G>A p.E951K | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV62864174; called by muse, mutect2, varscan2
- NCR2 | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753979828, COSV66100665; called by muse, mutect2, varscan2
- NEB | c.9412G>A p.D3138N | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs374760449; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEB | c.4130C>T p.T1377I | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV51421354; called by muse, mutect2, varscan2
- NEB | c.3597G>A p.W1199* | Nonsense Mutation (SNP) | VAF 80/284 reads (28%) | catalogued as COSV51421379; called by muse, varscan2
- NEFM | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV55332481; called by muse, mutect2, varscan2
- NELL1 | c.2089C>T p.Q697* | Nonsense Mutation (SNP) | VAF 72/160 reads (45%) | catalogued as COSV100125327, COSV54270575; called by muse, mutect2, varscan2
- NES | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 80/156 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs745935094, COSV63961256; called by muse, mutect2, varscan2
- NEXMIF | c.2321C>T p.S774F | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV50034805; called by muse, mutect2, varscan2
- NLRP13 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.047); catalogued as COSV61622103; called by muse, mutect2, varscan2
- NLRP3 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60219626; called by muse, mutect2, varscan2
- NLRP4 | c.1414C>T p.H472Y | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56713597; called by muse, mutect2, varscan2
- NPAP1 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61507569; called by muse, mutect2, varscan2
- NPFFR2 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866277955, COSV100440547, COSV58150261; called by muse, mutect2, varscan2
- NR1H4 | c.755C>T p.S252L (on ENST00000551379 / NM_001206993.2; = p.S238L on NM_005123.4) | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs764421287, COSV51852494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN1 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58457068; called by muse, mutect2, varscan2
- NUTM1 | c.3157C>T p.H1053Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100148790; called by muse, mutect2, varscan2
- NXF3 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.11); catalogued as COSV67702730; called by muse, mutect2, varscan2
- OAS1 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.777); catalogued as rs1334784975, COSV52536111; called by muse, mutect2, varscan2
- OBP2B | c.75C>T p.I25= | Splice Region (SNP) | VAF 15/26 reads (58%) | catalogued as COSV100922814; called by muse, mutect2, varscan2
- ODC1 | c.1256A>G p.Q419R | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52172413; called by muse, mutect2, varscan2
- OPRK1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs200377155, COSV55570954; called by muse, mutect2, varscan2
- OR1N2 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 68/84 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65460707; called by muse, mutect2, varscan2
- OR2L2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV63553622; called by muse, mutect2, varscan2
- OR2M2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 91/259 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62898478; called by muse, mutect2, varscan2
- OR2M7 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 125/301 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV58739273; called by muse, mutect2, varscan2
- OR2W3 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV64456290; called by muse, mutect2, varscan2
- OR4A47 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs374887866, COSV71444833; called by muse, mutect2, varscan2
- OR4C15 | c.753G>A p.M251I (on ENST00000314644; = p.M197I on NM_001001920.2) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1228047868, COSV58953152; called by muse, mutect2, varscan2
- OR4D2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101613857, COSV73459777; called by muse, mutect2, varscan2
- OR4K5 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs151215030; called by muse, mutect2, varscan2
- OR51A4 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100985403, COSV66749538; called by mutect2, varscan2
- OR51A4 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV66749541; called by muse, mutect2, varscan2
- OR5R1 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56571386; called by muse, mutect2, varscan2
- OR6K6 | c.922C>T p.L308F (on ENST00000368144; = p.L284F on NM_001005184.1) | Missense Mutation (SNP) | VAF 70/133 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.582); catalogued as COSV63744249; called by muse, mutect2, varscan2
- OR8D1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs1029345414, COSV63441743, COSV63442931; called by muse, mutect2, varscan2
- OR8K3 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.562); catalogued as COSV57131638; called by muse, mutect2, varscan2
- OR9G4 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs184358091, COSV57248746; called by muse, mutect2, varscan2
- OTOGL | c.4645G>A p.G1549R (on ENST00000547103; = p.G1540R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756353566, COSV54017517; called by muse, mutect2, varscan2
- OXA1L | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.025); catalogued as rs866495733, COSV53537277; called by muse, mutect2, varscan2
- OXER1 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54311089, COSV54312842; called by muse, mutect2, varscan2
- PADI3 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64934641; called by muse, mutect2, varscan2
- PAFAH1B1 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV68210260; called by muse, mutect2, varscan2
- PALLD | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as COSV54981869; called by muse, mutect2, varscan2
- PALLD | c.1514C>T p.T505I | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs751116198, COSV54981883, COSV54994055; called by muse, mutect2, varscan2
- PAPLN | c.3071G>A p.G1024E (on ENST00000554301; = p.G997E on NM_173462.4) | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV53718657; called by muse, mutect2, varscan2
- PAPPA2 | c.3409G>A p.D1137N | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as COSV62798969; called by muse, mutect2, varscan2
- PARD3 | c.3137C>T p.S1046F | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as COSV61051411; called by muse, mutect2, varscan2
- PCDH15 | c.5689G>A p.A1897T | Missense Mutation (SNP) | VAF 72/92 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV57320408; called by muse, mutect2, varscan2
- PCDH17 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.145); catalogued as COSV64974713; called by muse, mutect2, varscan2
- PCDH18 | c.1860A>G p.I620M | Missense Mutation (SNP) | VAF 109/267 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV61266733, COSV61268844; called by muse, mutect2, varscan2
- PCDHB11 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.081); catalogued as rs267600436, COSV61311970; called by muse, mutect2, varscan2
- PCDHB2 | c.1145G>A p.R382K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV50577709; called by muse, mutect2, varscan2
- PCDHB2 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs267600410, COSV50571388, COSV50577712; called by muse, mutect2, varscan2
- PCDHB8 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV50788401; called by muse, mutect2, varscan2
- PCDHGA11 | c.2276C>T p.S759F | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.495); catalogued as rs1225012888, COSV53925019, COSV53958700; called by muse, mutect2, varscan2
- PCDHGB1 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1448818942, COSV53958673; called by muse, mutect2, varscan2
- PCK1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as COSV60128425; called by muse, mutect2, varscan2
- PCLO | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 104/172 reads (60%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100427665; called by muse, mutect2, varscan2
- PCLO | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 99/169 reads (59%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV100427666; called by muse, mutect2, varscan2
- PCOLCE | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 81/123 reads (66%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV53826429; called by muse, mutect2, varscan2
- PDE2A | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 165/401 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57808078; called by muse, mutect2, varscan2
- PDE4DIP | c.5962C>T p.L1988= | Splice Region (SNP) | VAF 34/98 reads (35%) | catalogued as COSV57698636; called by muse, mutect2, varscan2
- PDE7B | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs752826780, COSV57498448; called by muse, mutect2, varscan2
- PDE8B | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs1389677367, COSV53735315; called by muse, mutect2, varscan2
- PGAP1 | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as rs556240126, COSV61324691; called by muse, mutect2, varscan2
- PGGHG | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV66887906; called by muse, mutect2, varscan2
- PHLDA1 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV56997503; called by muse, mutect2
- PINX1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV100134681; called by muse, mutect2
- PIP4K2A | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV60541116; called by muse, mutect2, varscan2
- PITPNM3 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1567693900, COSV52593134; called by muse, mutect2, varscan2
- PKD1L1 | c.3871G>A p.G1291R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as COSV56966552; called by muse, mutect2, varscan2
- PKDCC | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.074); catalogued as rs752291440, COSV54306979, COSV54308144; called by muse, mutect2, varscan2
- PLA2G3 | c.1280A>C p.K427T | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV53209881; called by muse, mutect2, varscan2
- PLA2R1 | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs371484082; called by muse, mutect2, varscan2
- PLAG1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 73/121 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0.346); catalogued as rs267601956, COSV57608998; called by muse, mutect2, varscan2
- PLCB4 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV53800835, COSV53809927; called by muse, mutect2, varscan2
- PLCL1 | c.2470C>T p.R824W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70836267; called by muse, mutect2, varscan2
- PNPLA8 | c.1342G>T p.D448Y | Missense Mutation (SNP) | VAF 74/109 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57552688; called by muse, mutect2, varscan2
- POFUT1 | c.493T>A p.F165I | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV65260226; called by muse, mutect2, varscan2
- PPP1R3A | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV52883768; called by muse, mutect2, varscan2
- PRAMEF18 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 86/431 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1484230227; called by muse, mutect2, varscan2
- PRDM16 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs780561119, COSV54592666; called by muse, mutect2
- PRLR | c.296A>C p.Y99S | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51496217; called by muse, mutect2, varscan2
- PRMT2 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 59/82 reads (72%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV52455316; called by muse, mutect2, varscan2
- PROKR2 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV54086987; called by muse, mutect2, varscan2
- PROM2 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV58298376; called by muse, mutect2, varscan2
- PROM2 | c.2360G>A p.W787* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as rs773940376, COSV58298544; called by muse, mutect2, varscan2
- PROM2 | c.2361G>A p.W787* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as rs1208605313, COSV58297133; called by muse, mutect2, varscan2
- PRR27 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 126/297 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV60640692; called by muse, mutect2, varscan2
- PSG1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 111/234 reads (47%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.773); catalogued as COSV54950260; called by muse, mutect2, varscan2
- PSTPIP2 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs551533898, COSV68957615; called by muse, mutect2, varscan2
- PTH2R | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55914860, COSV99064631; called by muse, mutect2, varscan2
- PTPRB | c.5623G>A p.E1875K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54242035; called by muse, mutect2, varscan2
- PTPRB | c.3874G>A p.D1292N | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as rs1250884124, COSV54242050; called by muse, mutect2, varscan2
- PTPRC | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs866816038, COSV61412614; called by muse, mutect2
- PTPRT | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1228688924, COSV61985097; called by muse, mutect2, varscan2
- PTPRT | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs868376470, COSV61962472; called by muse, mutect2, varscan2
- PXDC1 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100977187; called by muse, mutect2, varscan2
- PYGO2 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV63757069; called by muse, mutect2, varscan2
- RC3H2 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV61799977; called by muse, mutect2, varscan2
- RCBTB2 | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60650315; called by muse, mutect2, varscan2
- RECK | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as COSV65035494, COSV99061395; called by muse, mutect2
- REXO1 | c.2857G>A p.G953R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs377054348; called by muse, mutect2, varscan2
- RGS12 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60905780; called by muse, mutect2, varscan2
- RHOH | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67805797; called by muse, mutect2, varscan2
- RINT1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1440865817, COSV57558742; called by muse, mutect2
- RND1 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59045363; called by muse, mutect2, varscan2
- ROBO2 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV59913761; called by muse, mutect2, varscan2
- RPAP1 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 90/158 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760241698, COSV58539460; called by muse, mutect2, varscan2
- RPE65 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.222); catalogued as COSV52016372; called by muse, mutect2, varscan2
- RRM1 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.173); catalogued as COSV56164437; called by muse, mutect2, varscan2
- RSPO2 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV52645234; called by muse, mutect2, varscan2
- RTN1 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV50724388; called by muse, mutect2, varscan2
- RTN4RL1 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs201429067; called by muse, mutect2, varscan2
- RXFP2 | c.1844C>T p.S615F | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100034608, COSV53636174; called by muse, mutect2, varscan2
- RXYLT1 | c.1322A>G p.N441S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1340087199, COSV54168565; called by muse, mutect2
- RYR1 | c.3566C>T p.P1189L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs988702965, COSV62098923; called by muse, mutect2, varscan2
- RYR3 | c.2900C>T p.P967L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66791888; called by muse, mutect2, varscan2
- SAMHD1 | c.209-1G>A p.X70_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as COSV53429928, COSV53431660; called by muse, mutect2, varscan2
- SCN10A | c.4865C>T p.S1622F | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV71861690; called by muse, mutect2, varscan2
- SERPINB3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as rs1185057024, COSV52191885; called by muse, mutect2, varscan2
- SEZ6L2 | c.761G>C p.G254A (on ENST00000308713 / NM_001114099.3; = p.G184A on NM_012410.4) | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58099828; called by muse, mutect2, varscan2
- SGCZ | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV65994859; called by muse, mutect2, varscan2
- SGF29 | c.53A>T p.H18L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as rs1244820721, COSV57681879; called by muse, mutect2
- SGF29 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV57681887; called by muse, mutect2
- SH2D3C | c.1634C>T p.P545L (on ENST00000314830 / NM_170600.3; = p.P388L on NM_005489.4) | Missense Mutation (SNP) | VAF 77/97 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59123826; called by muse, mutect2, varscan2
- SH3GL2 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66050899; called by muse, mutect2, varscan2
- SHC2 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs752640677, COSV52746404; called by muse, mutect2, varscan2
- SKAP2 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61723993; called by muse, mutect2, varscan2
- SLC22A2 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs755309980, COSV65266647; called by muse, mutect2, varscan2
- SLC25A36 | c.844C>T p.R282C (on ENST00000324194 / NM_001104647.3; = p.R281C on NM_018155.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1384331771, COSV60781447; called by muse, mutect2, varscan2
- SLC25A37 | c.775A>G p.K259E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51564378; called by muse, mutect2, varscan2
- SLC2A12 | c.224G>A p.S75N | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV51600298; called by muse, mutect2, varscan2
- SLC38A1 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as COSV67062947, COSV67063639; called by muse, mutect2, varscan2
- SLC5A7 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.066); catalogued as rs764287242, COSV50889123; called by muse, mutect2, varscan2
- SLC6A1 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as COSV55115740; called by muse, mutect2, varscan2
- SLC6A13 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV58257489; called by muse, mutect2, varscan2
- SLC9C2 | c.2833G>A p.D945N | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV62944812, COSV62946065; called by muse, mutect2, varscan2
- SLCO1A2 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56603549; called by muse, mutect2, varscan2
- SLCO1B1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as COSV57011804; called by muse, mutect2, varscan2
- SLFN11 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV57697855; called by muse, mutect2, varscan2
- SLIT2 | c.4436G>A p.R1479Q | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.253); catalogued as rs147726667; called by muse, mutect2, varscan2
- SMARCC2 | c.2704A>G p.K902E | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57219086; called by muse, mutect2, varscan2
- SNCAIP | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.385); catalogued as rs534709742, COSV54401767; called by muse, mutect2, varscan2
- SNCAIP | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV54411363; called by muse, mutect2, varscan2
- SNTG2 | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs769858572, COSV57985869; called by muse, mutect2, varscan2
- SORBS1 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV53354034; called by muse, mutect2, varscan2
- SORL1 | c.2618C>T p.S873F | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV52755317; called by muse, mutect2, varscan2
- SPAG17 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV60459858; called by muse, mutect2, varscan2
- SPAM1 | c.1234G>A p.G412S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs754085043, COSV56144312; called by muse, mutect2, varscan2
- SPEG | c.8668G>A p.G2890R | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV56670212; called by muse, mutect2, varscan2
- SRGAP3 | c.2362G>A p.G788S | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as rs773096168, COSV64533888; called by muse, mutect2, varscan2
- SSH3 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs773991846, COSV57384978; called by muse, varscan2
- STK24 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as rs1241810596, COSV64823013; called by muse, mutect2, varscan2
- STYXL1 | c.698-1G>A p.X233_splice | Splice Site (SNP) | VAF 27/90 reads (30%) | catalogued as rs782725497, COSV50389181; called by muse, mutect2, varscan2
- SVEP1 | c.6109C>T p.R2037W | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52839841; called by muse, mutect2, varscan2
- SYBU | c.91C>T p.R31W (on ENST00000276646 / NM_001099754.2; = p.R30W on NM_017786.6) | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs750745801, COSV52618696; called by muse, mutect2, varscan2
- TBC1D4 | c.3583G>A p.D1195N | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as COSV100884600, COSV66489472; called by muse, mutect2, varscan2
- TBX4 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); catalogued as COSV53607668; called by muse, mutect2, varscan2
- TCEA3 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV71531970; called by muse, mutect2, varscan2
- TCF25 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54525569; called by muse, mutect2, varscan2
- TCHH | c.503G>C p.R168P | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); catalogued as COSV64275171, COSV64276373; called by muse, mutect2, varscan2
- TECRL | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.084); catalogued as COSV67087441, COSV67091230; called by muse, mutect2, varscan2
- TENM1 | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100949310, COSV64433126; called by muse, mutect2, varscan2
- THBS3 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as rs1456106679, COSV64249510; called by muse, mutect2
- THSD7A | c.4796G>A p.G1599E | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as rs1376072465, COSV68471875; called by muse, mutect2, varscan2
- THSD7B | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs561877625, COSV55653247; called by muse, mutect2, varscan2
- TIGIT | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs146935299; called by muse, mutect2, varscan2
- TLK2 | c.2174G>A p.R725Q (on ENST00000326270 / NM_001284333.2; = p.R703Q on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as rs769484053, COSV58299162; called by muse, mutect2, varscan2
- TLL1 | c.2443-1G>A p.X815_splice | Splice Site (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99286229; called by muse, mutect2
- TLR3 | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.65); PolyPhen benign (0.073); catalogued as COSV57168823; called by muse, mutect2, varscan2
- TLR6 | c.1695A>T p.E565D | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV67935318; called by muse, mutect2, varscan2
- TMEM130 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782001740, COSV59559397; called by muse, mutect2, varscan2
- TMEM169 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.847); catalogued as COSV55265398; called by muse, mutect2, varscan2
- TMEM266 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs376932946; called by muse, mutect2, varscan2
- TMEM63C | c.2047C>T p.H683Y | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as COSV53604071; called by muse, mutect2, varscan2
- TMEM74 | c.752T>G p.M251R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52463506; called by muse, mutect2, varscan2
- TNFRSF11B | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52071450; called by muse, mutect2, varscan2
- TNNC2 | c.134G>C p.R45T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV65332680; called by muse, mutect2, varscan2
- TNPO3 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs1298089474, COSV55282157; called by muse, mutect2, varscan2
- TNR | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 106/172 reads (62%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV54888089; called by muse, varscan2
- TNR | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.629); catalogued as rs775934150, COSV54888103; called by muse, varscan2
- TNRC6C | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV56945854; called by muse, mutect2, varscan2
- TOGARAM1 | c.3611C>T p.S1204F | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV63892009, COSV63892504; called by muse, mutect2, varscan2
- TOM1 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV101146530; called by muse, mutect2, varscan2
- TOX | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as COSV63846430; called by muse, mutect2
- TP53BP1 | c.1960C>T p.H654Y | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.062); catalogued as COSV99779829; called by muse, mutect2, varscan2
- TRAV4 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as rs938325267; called by muse, mutect2, varscan2
- TRIO | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as COSV60084819; called by muse, mutect2, varscan2
- TRIT1 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV57548543; called by muse, mutect2, varscan2
- TRPC5 | c.2360G>A p.S787N | Missense Mutation (SNP) | VAF 154/173 reads (89%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV53291734; called by muse, mutect2, varscan2
- TSPOAP1 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99270126; called by muse, mutect2, varscan2
- TTN | c.68342G>A p.R22781K (on ENST00000591111; = p.R15357K on NM_003319.4) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | PolyPhen benign (0.009); catalogued as rs780420383, COSV60099375; called by muse, varscan2
- TTN | c.28702G>A p.E9568K (on ENST00000591111; = p.E8641K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/157 reads (45%) | PolyPhen benign (0.038); catalogued as COSV60099420; called by muse, mutect2, varscan2
- TTN | c.3029G>A p.S1010N (on ENST00000591111; = p.S964N on NM_003319.4) | Missense Mutation (SNP) | VAF 30/59 reads (51%) | PolyPhen probably damaging (0.994); catalogued as COSV59905179; called by muse, mutect2, varscan2
- UBXN10 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs567277729, COSV66772241; called by muse, mutect2, varscan2
- UGT2B4 | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs752649345, COSV59317633; called by muse, mutect2, varscan2
- UGT3A1 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.326); catalogued as rs759699054, COSV99954333, COSV99954976; called by muse, mutect2, varscan2
- UGT3A1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.102); catalogued as COSV57098580; called by muse, mutect2, varscan2
- UHRF1 | c.115G>A p.E39K (on ENST00000612630 / NM_001290050.1; = p.E52K on NM_013282.4) | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.088); catalogued as COSV53574850; called by muse, mutect2, varscan2
- UNC13D | c.2492A>T p.E831V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV52884953; called by muse, mutect2, varscan2
- UNC93A | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100023290, COSV57807260; called by muse, mutect2, varscan2
- USP2 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52729674; called by muse, mutect2, varscan2
- UTP14C | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV73000682; called by muse, mutect2, varscan2
- VPS39 | c.570G>A p.V190= (on ENST00000348544 / NM_001301138.2; = p.V179= on NM_015289.5) | Splice Region (SNP) | VAF 25/94 reads (27%) | catalogued as rs1334630586, COSV58790017; called by muse, mutect2, varscan2
- VSTM4 | c.837+1G>A p.X279_splice | Splice Site (SNP) | VAF 93/131 reads (71%) | catalogued as COSV100251304; called by muse, mutect2, varscan2
- VSTM4 | c.837G>A p.L279= | Splice Region (SNP) | VAF 94/133 reads (71%) | catalogued as COSV60528173; called by muse, mutect2, varscan2
- VWA3B | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV68243367; called by muse, mutect2, varscan2
- WDFY3 | c.10477G>A p.E3493K | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV55702371, COSV99886381; called by muse, mutect2, varscan2
- WIPI1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs776365690, COSV50929529; called by muse, mutect2, varscan2
- WNK4 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53820867; called by muse, mutect2, varscan2
- WNT2 | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as rs1348427387, COSV55411299; called by muse, mutect2, varscan2
- WRN | c.2216T>C p.V739A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53300862; called by muse, mutect2, varscan2
- XDH | c.3872T>C p.V1291A | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV65149049; called by muse, mutect2, varscan2
- XDH | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770700444, COSV65147807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XPR1 | c.1900del p.L634* | Frame Shift Del (DEL) | VAF 57/116 reads (49%) | catalogued as rs1473032655; called by pindel, varscan2
- ZBBX | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56790820; called by muse, mutect2, varscan2
- ZC3H18 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56325003; called by muse, mutect2, varscan2
- ZC3H4 | c.3629C>T p.T1210I | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.648); catalogued as COSV99451735; called by muse, mutect2, varscan2
- ZDHHC11 | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 99/381 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52068813; called by muse, mutect2, varscan2
- ZEB2 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57953031; called by muse, mutect2, varscan2
- ZFHX4 | c.10327C>T p.P3443S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV50646995, COSV99258741; called by muse, mutect2, varscan2
- ZMYM4 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.187); catalogued as COSV58911266; called by muse, mutect2, varscan2
- ZNF160 | c.980A>T p.Y327F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV61999823; called by muse, mutect2, varscan2
- ZNF211 | c.139T>C p.W47R (on ENST00000347302 / NM_198855.4; = p.W60R on NM_006385.5) | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53742460; called by muse, mutect2, varscan2
- ZNF318 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); catalogued as COSV58933008; called by muse, mutect2, varscan2
- ZNF414 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs764033116, COSV55321752; called by muse, mutect2, varscan2
- ZNF420 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV58494361; called by muse, mutect2, varscan2
- ZNF440 | c.611T>A p.F204Y | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV58371273; called by muse, mutect2, varscan2
- ZNF48 | c.1742G>A p.G581D | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs780675170, COSV60783366; called by muse, mutect2, varscan2
- ZNF485 | c.1294C>T p.H432Y | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62424455, COSV62425110; called by muse, mutect2, varscan2
- ZNF521 | c.569A>T p.K190M | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64127547; called by muse, mutect2, varscan2
- ZNF560 | c.1976A>T p.N659I | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV56868232; called by muse, mutect2, varscan2
- ZNF619 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV59030234; called by muse, mutect2, varscan2
- ZNF671 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs776949733, COSV58053105, COSV58054320; called by muse, mutect2, varscan2
- ZNF677 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.549); catalogued as rs866250234, COSV61719766; called by muse, mutect2, varscan2
- ZNF768 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.558); catalogued as COSV63321958; called by muse, mutect2, varscan2
- ZNF770 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV62544360; called by muse, mutect2
- ZNF793 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs377400755; called by muse, mutect2, varscan2
- ZNF804A | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV56440249; called by muse, mutect2, varscan2
- ZNF804B | c.1921C>A p.P641T | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100307016, COSV60830209; called by muse, mutect2, varscan2
- ZP1 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53924630; called by muse, mutect2, varscan2
- ZSCAN5B | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769100111, COSV62839611; called by muse, mutect2, varscan2
- AJAP1 | c.1157_1163+16del p.X386_splice | Splice Site (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel
- ASZ1 | c.1344_1346del p.S448del | In Frame Del (DEL) | VAF 31/62 reads (50%) | called by pindel, varscan2
- CLDN1 | c.76dup p.A26Gfs*43 | Frame Shift Ins (INS) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- ICA1L | c.684+1del p.X228_splice | Splice Site (DEL) | VAF 125/289 reads (43%) | called by mutect2, pindel, varscan2
- IGHV1OR15-9 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NACC2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- PRAMEF14 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- SLCO4A1 | c.2078_2088del p.S693* | Frame Shift Del (DEL) | VAF 32/136 reads (24%) | called by mutect2, pindel, varscan2
- ABCA13 | c.6819C>T p.S2273= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV70030333; called by muse, mutect2, varscan2
- ABCA4 | c.5811C>T p.I1937= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as rs759451313, COSV64673995; called by muse, mutect2, varscan2
- ABCA6 | c.3027C>T p.L1009= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV52639333; called by muse, mutect2, varscan2
- ABCC9 | c.3729G>A p.S1243= | Silent (SNP) | VAF 88/231 reads (38%) | catalogued as rs140182559; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACSM5 | c.105C>T p.I35= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs761085728, COSV59371645; called by muse, mutect2, varscan2
- ACVR1C | c.756C>T p.F252= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV54646563; called by muse, mutect2, varscan2
- ADA | c.777C>T p.F259= | Silent (SNP) | VAF 77/186 reads (41%) | catalogued as rs772309012, COSV63068955; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAM12 | c.1455C>T p.S485= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV64107534; called by muse, mutect2, varscan2
- ADAM29 | c.1521G>A p.R507= | Silent (SNP) | VAF 54/98 reads (55%) | catalogued as rs267600092, COSV63661987, COSV63664066; called by muse, mutect2, varscan2
- ADAM9 | c.724C>T p.L242= | Silent (SNP) | VAF 44/64 reads (69%) | catalogued as COSV65946708; called by muse, mutect2, varscan2
- ADAMTS6 | c.2608T>C p.L870= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs781071055, COSV58683248; called by muse, mutect2, varscan2
- ADGRB3 | c.3171G>A p.K1057= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs775608160, COSV53246497; called by mutect2, varscan2
- AIP | c.972C>T p.F324= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV54160827; called by muse, mutect2, varscan2
- ANKRD30A | c.543G>A p.T181= (on ENST00000611781; = p.T125= on NM_052997.2) | Silent (SNP) | VAF 42/57 reads (74%) | catalogued as rs748801395, COSV64609214, COSV64609913; called by muse, varscan2
- ANO10 | c.1692T>C p.V564= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV52731612; called by muse, mutect2, varscan2
- ARGFX | c.6G>A p.R2= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV57682428; called by muse, varscan2
- ARHGEF17 | c.678G>A p.G226= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV55232998; called by muse, varscan2
- ASAH2 | c.84C>T p.L28= | Silent (SNP) | VAF 35/47 reads (74%) | catalogued as COSV100269850, COSV61483172, COSV61483522; called by muse, mutect2, varscan2
- BCL2A1 | c.492C>T p.I164= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV51213282; called by muse, mutect2, varscan2
- BCO2 | c.1716C>T p.F572= | Silent (SNP) | VAF 29/35 reads (83%) | catalogued as COSV63063560; called by muse, mutect2, varscan2
- BEND2 | c.1548G>A p.K516= | Silent (SNP) | VAF 212/233 reads (91%) | catalogued as COSV101192286, COSV66215997; called by muse, mutect2, varscan2
- BNIP5 | c.1734G>A p.L578= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV71325323; called by muse, mutect2, varscan2
- C15orf40 | c.93G>A p.K31= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs372883978, COSV55604073; called by muse, mutect2, varscan2
- C1QTNF6 | c.123C>T p.I41= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV55396165; called by muse, mutect2, varscan2
- C5 | c.1635C>T p.I545= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as rs1187883385, COSV56327944; called by muse, mutect2, varscan2
- CACNA1I | c.1965C>T p.V655= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs367896597; called by muse, mutect2, varscan2
- CACNA1I | c.4119C>T p.L1373= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV60809845; called by muse, mutect2, varscan2
- CACNA1S | c.3507C>T p.L1169= | Silent (SNP) | VAF 34/47 reads (72%) | catalogued as COSV62939282; called by muse, mutect2, varscan2
- CACNA2D3 | c.2943C>T p.T981= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV55543471; called by muse, mutect2, varscan2
- CACNG4 | c.318C>T p.A106= | Silent (SNP) | VAF 74/164 reads (45%) | catalogued as COSV50925422; called by muse, mutect2, varscan2
- CAMSAP1 | c.1062C>T p.H354= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100410508, COSV56723195; called by muse, mutect2, varscan2
- CAPN15 | c.816G>A p.R272= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs776585616, COSV54836353; called by muse, varscan2
- CARD11 | c.762G>A p.K254= | Silent (SNP) | VAF 96/178 reads (54%) | catalogued as rs572758348, COSV67799533; called by muse, varscan2
- CCDC141 | c.3015G>A p.K1005= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV55374374; called by muse, mutect2, varscan2
- CCDC34 | c.849G>A p.A283= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs749059795, COSV60820825; called by muse, mutect2, varscan2
- CD163 | c.3210C>T p.F1070= | Silent (SNP) | VAF 63/152 reads (41%) | catalogued as COSV63132949; called by muse, mutect2, varscan2
- CDS2 | c.1299C>T p.I433= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs138757559; called by muse, mutect2, varscan2
- CFLAR | c.1419G>A p.K473= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV58580360; called by muse, mutect2, varscan2
- CHD2 | c.5223C>T p.F1741= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV101244735; called by muse, mutect2, varscan2
- CHERP | c.2028C>T p.L676= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs761498031, COSV52224831; called by muse, mutect2, varscan2
- CHRNB4 | c.852C>T p.I284= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs377658350; called by muse, mutect2, varscan2
- CILP | c.321G>A p.Q107= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV56024708, COSV99973792; called by muse, mutect2, varscan2
- CKAP2L | c.591G>A p.R197= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV56696639; called by muse, mutect2, varscan2
- CMIP | c.1632C>T p.A544= (on ENST00000537098 / NM_198390.2; = p.A450= on NM_030629.3) | Silent (SNP) | VAF 29/45 reads (64%) | catalogued as COSV101220937, COSV67698508; called by muse, mutect2, varscan2
- CNR1 | c.1059C>T p.I353= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as rs967859759, COSV62987586; called by muse, mutect2, varscan2
- COL24A1 | c.993G>A p.G331= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV65307238; called by muse, mutect2, varscan2
- COL6A3 | c.9093C>T p.S3031= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs757423987, COSV55091779; called by muse, mutect2, varscan2
- CRYBG2 | c.3150C>T p.T1050= | Silent (SNP) | VAF 73/187 reads (39%) | catalogued as rs759764606, COSV100366316; called by muse, mutect2, varscan2
- CSMD3 | c.8058C>T p.T2686= (on ENST00000297405 / NM_001363185.1; = p.T2582= on NM_052900.3) | Silent (SNP) | VAF 60/104 reads (58%) | catalogued as COSV52324894, COSV99825550; called by muse, mutect2, varscan2
- CYP2R1 | c.969T>C p.I323= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV58127767; called by muse, mutect2, varscan2
- DENND3 | c.1374G>A p.K458= | Silent (SNP) | VAF 45/170 reads (26%) | catalogued as rs1304701441, COSV52802831; called by muse, mutect2, varscan2
- DLGAP4 | c.132C>T p.A44= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs1161100365, COSV59418359; called by muse, mutect2, varscan2
- DNAH11 | c.10542G>A p.L3514= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV60958137; called by muse, mutect2, varscan2
- DNAH9 | c.7848C>T p.S2616= | Silent (SNP) | VAF 94/214 reads (44%) | catalogued as COSV52352370; called by muse, mutect2, varscan2
- DRD5 | c.144C>T p.T48= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV58578441; called by muse, mutect2, varscan2
- DUOX2 | c.1656C>T p.P552= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV66530922; called by muse, mutect2, varscan2
- DYNC1H1 | c.13599C>T p.S4533= | Silent (SNP) | VAF 29/35 reads (83%) | catalogued as rs1319903649, COSV64137503; called by muse, mutect2, varscan2
- EDNRA | c.255G>A p.V85= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV60097926; called by muse, mutect2, varscan2
- EEF2K | c.441C>T p.F147= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV53782428; called by muse, mutect2, varscan2
- ELF5 | c.18C>T p.H6= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs756495257, COSV56629023; called by muse, mutect2, varscan2
- ENOSF1 | c.939C>T p.S313= (on ENST00000340116 / NM_001354066.2; = p.S265= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/194 reads (30%) | catalogued as COSV51892812; called by muse, mutect2, varscan2
- EPHA4 | c.1194C>T p.V398= | Silent (SNP) | VAF 170/335 reads (51%) | catalogued as COSV56034577; called by muse, mutect2, varscan2
- EPPK1 | c.2172C>T p.I724= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs375827456; called by muse, mutect2, varscan2
- ERBB4 | c.462C>T p.F154= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs749011668, COSV53537437; called by muse, mutect2, varscan2
- ERC2 | c.2442G>A p.Q814= | Silent (SNP) | VAF 54/189 reads (29%) | catalogued as COSV55619469, COSV55626117; called by muse, mutect2, varscan2
- EXPH5 | c.234A>G p.L78= | Silent (SNP) | VAF 42/53 reads (79%) | catalogued as rs1565810134, COSV56202978; called by muse, mutect2, varscan2
- FAM83D | c.861C>T p.F287= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV54157611; called by muse, mutect2, varscan2
- FBN3 | c.4515C>T p.S1505= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV54462244; called by muse, mutect2, varscan2
- FCGBP | c.1785G>A p.L595= | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2
- FCRL6 | c.780C>T p.S260= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV58941337; called by muse, mutect2, varscan2
- FGF21 | c.123G>A p.G41= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV55810498; called by muse, mutect2, varscan2
- FIG4 | c.1794C>T p.F598= | Silent (SNP) | VAF 30/38 reads (79%) | catalogued as COSV57787977; called by muse, mutect2, varscan2
- FLG | c.11562G>A p.R3854= | Silent (SNP) | VAF 92/325 reads (28%) | catalogued as COSV64242549; called by muse, mutect2, varscan2
- FOLH1 | c.462T>A p.V154= | Silent (SNP) | VAF 79/216 reads (37%) | catalogued as COSV57049795; called by muse, mutect2, varscan2
- FOXI1 | c.144C>T p.S48= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV60388778; called by muse, mutect2, varscan2
- FPR3 | c.426C>A p.A142= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV59330195; called by muse, mutect2, varscan2
- FYB1 | c.1668G>A p.R556= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100684965, COSV60947669; called by muse, mutect2, varscan2
- GAD1 | c.1635G>A p.L545= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV64026145; called by muse, mutect2, varscan2
- GAPVD1 | c.1959G>A p.E653= | Silent (SNP) | VAF 41/54 reads (76%) | catalogued as COSV52923440; called by muse, mutect2, varscan2
- GCG | c.339C>T p.G113= | Silent (SNP) | VAF 129/208 reads (62%) | catalogued as COSV64961449; called by muse, mutect2, varscan2
- GHRHR | c.837C>T p.S279= | Silent (SNP) | VAF 43/157 reads (27%) | catalogued as rs748290640, COSV100396421, COSV58196674; called by muse, mutect2, varscan2
- GIPC1 | c.910C>T p.L304= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV52875319; called by muse, mutect2, varscan2
- GJB3 | c.420C>T p.I140= | Silent (SNP) | VAF 57/130 reads (44%) | catalogued as COSV64904628, COSV64904765; called by muse, mutect2, varscan2
- GOLGA8A | c.1806G>A p.E602= (on ENST00000432566; = p.E574= on NM_181077.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV62169883; called by mutect2, varscan2
- GRIN1 | c.399C>T p.I133= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV59296051; called by muse, mutect2
- GRIN1 | c.2580G>A p.K860= | Silent (SNP) | VAF 37/69 reads (54%) | catalogued as COSV59296069; called by muse, mutect2, varscan2
- GRXCR1 | c.858G>A p.K286= | Silent (SNP) | VAF 59/162 reads (36%) | catalogued as COSV67671996; called by muse, mutect2, varscan2
- GYPE | c.75G>A p.V25= | Silent (SNP) | VAF 20/172 reads (12%) | catalogued as COSV62262251; called by muse, mutect2, varscan2
- HCRTR2 | c.195C>T p.F65= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as COSV63796144; called by muse, mutect2, varscan2
- HGD | c.408C>T p.F136= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV52198471; called by muse, mutect2, varscan2
- HTR5A | c.816G>A p.G272= | Silent (SNP) | VAF 42/60 reads (70%) | catalogued as COSV55283716; called by muse, mutect2, varscan2
- IFNA16 | c.273C>T p.F91= | Silent (SNP) | VAF 69/83 reads (83%) | catalogued as rs1204694341, COSV66510050; called by muse, mutect2, varscan2
- IGHV3-11 | c.27C>T p.F9= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs782585549; called by muse, mutect2, varscan2
- IGHV3-15 | c.138C>T p.F46= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as rs782067350; called by muse, mutect2, varscan2
- IGHV3-73 | c.27C>T p.F9= | Silent (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- IGLV6-57 | c.282C>T p.S94= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV66504137; called by muse, mutect2, varscan2
- IL1F10 | c.192G>A p.G64= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV61750549; called by muse, mutect2, varscan2
- INHBE | c.813C>T p.Y271= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs746048975, COSV56988238; called by muse, varscan2
- IPO8 | c.579C>T p.S193= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as rs112676658, COSV56242102; called by muse, mutect2, varscan2
- ITIH4 | c.2238C>T p.L746= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as COSV56574686; called by muse, mutect2, varscan2
- KCMF1 | c.375G>A p.T125= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs764731804, COSV101301227, COSV69054498; called by muse, mutect2, varscan2
- KCNB1 | c.2073C>T p.Y691= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV65568537; called by muse, mutect2, varscan2
- KCNH2 | c.453C>T p.P151= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as CD001499; called by muse, mutect2, varscan2
- KDM2B | c.1608G>A p.E536= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV100997209; called by muse, mutect2, varscan2
- KIF5A | c.741C>T p.A247= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs769133499, COSV54056036; called by muse, mutect2, varscan2
- KIN | c.738G>A p.Q246= | Silent (SNP) | VAF 40/48 reads (83%) | catalogued as COSV65430719; called by muse, mutect2, varscan2
- KLHDC7A | c.2310C>T p.P770= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV68769913; called by muse, mutect2, varscan2
- KRTAP19-4 | c.210G>A p.T70= | Silent (SNP) | VAF 70/94 reads (74%) | catalogued as rs1387536915, COSV61858313; called by muse, varscan2
- KSR2 | c.1965C>T p.F655= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs1295958309, COSV56664593; called by muse, mutect2, varscan2
- LACTB | c.36T>A p.A12= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV99978838; called by muse, mutect2
- LARGE2 | c.1422C>T p.F474= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs138897549; called by muse, mutect2, varscan2
- LARP4 | c.1182C>T p.S394= | Silent (SNP) | VAF 58/151 reads (38%) | catalogued as COSV53323009; called by muse, mutect2, varscan2
- LCN15 | c.189C>T p.I63= | Silent (SNP) | VAF 64/120 reads (53%) | catalogued as COSV60210341, COSV60210430; called by muse, mutect2, varscan2
- LCT | c.3942C>T p.V1314= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as rs772413669, COSV51550440; called by muse, mutect2, varscan2
- LEPR | c.1059C>T p.I353= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as COSV100756604, COSV60756294; called by muse, mutect2, varscan2
- LIMK2 | c.1173C>T p.F391= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV59182709; called by muse, mutect2, varscan2
- LRFN2 | c.1626C>T p.I542= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs1348883450, COSV57829295, COSV57832358; called by muse, mutect2, varscan2
- LRP1B | c.1863G>A p.R621= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV67186904; called by muse, mutect2, varscan2
- LRRK1 | c.316C>T p.L106= | Silent (SNP) | VAF 78/122 reads (64%) | catalogued as COSV52609906; called by muse, mutect2, varscan2
- LRRK2 | c.3072G>A p.T1024= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs201407012, COSV54155014; called by muse, mutect2, varscan2
- LSM10 | c.354C>G p.P118= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as COSV59872388, COSV59872661; called by muse, mutect2, varscan2
- LTBP2 | c.3621C>T p.F1207= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs747362950, COSV99999755; called by muse, varscan2
- MAGEB6B | c.51G>A p.E17= | Silent (SNP) | VAF 55/65 reads (85%) | catalogued as COSV69689974; called by muse, mutect2, varscan2
- MAP3K21 | c.1752G>A p.R584= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV64040994, COSV64041824; called by muse, mutect2, varscan2
- MAPK7 | c.558C>T p.S186= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV55190637; called by muse, mutect2, varscan2
- MARCO | c.831G>A p.G277= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV59055105; called by muse, mutect2, varscan2
- MDN1 | c.6867C>T p.F2289= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV65522515; called by muse, mutect2, varscan2
- MERTK | c.552C>T p.I184= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs148690514, COSV54927275; called by muse, mutect2, varscan2
- MRGPRX1 | c.645C>T p.Y215= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1245445796, COSV57107574, COSV57108980; called by muse, mutect2, varscan2
- MUC16 | c.10617C>T p.S3539= | Silent (SNP) | VAF 54/184 reads (29%) | catalogued as COSV67469574; called by muse, mutect2, varscan2
- MUC16 | c.5280G>A p.V1760= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV67469584; called by muse, mutect2, varscan2
- MYO18B | c.2634C>T p.I878= | Silent (SNP) | VAF 103/262 reads (39%) | catalogued as rs866173516, COSV59135803; called by muse, mutect2, varscan2
- MYO9B | c.3510G>A p.K1170= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV101261298; called by muse, mutect2, varscan2
- NCAPG | c.1716C>T p.S572= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV52270608; called by muse, mutect2, varscan2
- NCKAP5 | c.3546C>T p.S1182= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs554514177, COSV100492178, COSV58446620; called by muse, mutect2, varscan2
- NES | c.2587C>T p.L863= | Silent (SNP) | VAF 21/151 reads (14%) | catalogued as rs774622704, COSV63960698; called by muse, mutect2, varscan2
- NFKBIL1 | c.477C>T p.A159= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV65990456; called by muse, mutect2, varscan2
- NPLOC4 | c.1326C>T p.P442= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs764298862, COSV58616480; called by muse, mutect2, varscan2
- NPY5R | c.1014G>A p.E338= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as COSV58452205; called by muse, mutect2, varscan2
- NR4A1 | c.1092C>T p.L364= | Silent (SNP) | VAF 59/129 reads (46%) | catalogued as COSV54482899; called by muse, mutect2, varscan2
- NRXN1 | c.1347G>A p.R449= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as rs769308668, COSV58457029; called by muse, mutect2, varscan2
- NRXN3 | c.618C>T p.P206= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV73585666; called by muse, mutect2, varscan2
- NUB1 | c.579C>T p.F193= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV63426748; called by muse, mutect2
- NUTM1 | c.3156C>T p.S1052= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100148842; called by muse, mutect2, varscan2
- OPRL1 | c.199C>T p.L67= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV61091834; called by muse, mutect2, varscan2
- OR11G2 | c.189C>T p.I63= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs774718962, COSV62132384; called by muse, mutect2, varscan2
- OR14C36 | c.627C>T p.F209= | Silent (SNP) | VAF 49/148 reads (33%) | catalogued as COSV58601468; called by muse, mutect2, varscan2
- OR1C1 | c.312C>T p.F104= | Silent (SNP) | VAF 38/61 reads (62%) | catalogued as rs373351363, COSV68715780; called by muse, mutect2, varscan2
- OR2L13 | c.618C>T p.L206= | Silent (SNP) | VAF 51/157 reads (32%) | catalogued as COSV63547771, COSV63553626; called by muse, mutect2, varscan2
- OR2T2 | c.39C>T p.F13= | Silent (SNP) | VAF 53/352 reads (15%) | catalogued as rs779374477, COSV61617823; called by muse, mutect2, varscan2
- OR2T2 | c.204C>T p.S68= | Silent (SNP) | VAF 72/253 reads (28%) | catalogued as rs745712523, COSV61618211; called by muse, mutect2, varscan2
- OR4C11 | c.66G>A p.Q22= | Silent (SNP) | VAF 33/36 reads (92%) | catalogued as COSV56353048; called by muse, mutect2, varscan2
- OR51B6 | c.837C>T p.F279= | Silent (SNP) | VAF 61/128 reads (48%) | catalogued as COSV66513170; called by muse, mutect2, varscan2
- OR51M1 | c.651C>T p.F217= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV60784676; called by muse, mutect2, varscan2
- OR52E4 | c.273C>T p.L91= | Silent (SNP) | VAF 33/162 reads (20%) | catalogued as COSV57624929; called by muse, mutect2, varscan2
- OR52I2 | c.297G>A p.V99= | Silent (SNP) | VAF 59/319 reads (18%) | catalogued as rs145090174, COSV57045156; called by muse, mutect2, varscan2
- OR5D18 | c.189C>T p.F63= | Silent (SNP) | VAF 87/221 reads (39%) | catalogued as rs145410438, COSV61736632; called by muse, mutect2, varscan2
- OR5L2 | c.36C>T p.F12= | Silent (SNP) | VAF 85/238 reads (36%) | catalogued as COSV65724190; called by muse, mutect2, varscan2
- OR6N1 | c.201C>T p.S67= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as rs553836664, COSV58648750; called by muse, mutect2, varscan2
- OR8G2P | c.663C>T p.I221= | Silent (SNP) | VAF 53/74 reads (72%) | catalogued as rs1345334266; called by muse, mutect2, varscan2
- OTOGL | c.2628C>T p.N876= (on ENST00000547103; = p.N867= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as rs371565107; ClinVar: likely benign; called by muse, mutect2, varscan2
- PAPPA | c.1833C>T p.S611= | Silent (SNP) | VAF 122/154 reads (79%) | catalogued as COSV60284505; called by muse, mutect2, varscan2
- PARP6 | c.783C>T p.P261= | Silent (SNP) | VAF 112/212 reads (53%) | catalogued as COSV53003437; called by muse, mutect2, varscan2
- PARP9 | c.282C>T p.T94= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs368112511; called by muse, mutect2, varscan2
- PAX4 | c.423G>A p.R141= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58389092; called by muse, mutect2
- PCDHB10 | c.1965C>T p.T655= | Silent (SNP) | VAF 32/44 reads (73%) | catalogued as COSV53379369; called by muse, varscan2
- PCDHB11 | c.2103C>T p.F701= | Silent (SNP) | VAF 56/166 reads (34%) | catalogued as rs1371011440, COSV61311960; called by muse, mutect2, varscan2
- PCDHB12 | c.846C>T p.S282= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV53397118, COSV53397743; called by muse, mutect2, varscan2
- PCDHGA3 | c.399C>T p.F133= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV53958650; called by muse, mutect2
- PCDHGB6 | c.429C>T p.F143= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV53899918; called by muse, mutect2, varscan2
- PCNX2 | c.4815A>G p.Q1605= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV50807141; called by muse, mutect2, varscan2
- PDIA4 | c.1356C>T p.A452= (on ENST00000286091 / NM_001371244.1; = p.A451= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 98/156 reads (63%) | catalogued as rs1373040270, COSV53724967; called by muse, mutect2, varscan2
- PEX12 | c.120G>A p.V40= | Silent (SNP) | VAF 46/82 reads (56%) | catalogued as COSV56778130; called by muse, varscan2
- PGGHG | c.1389C>T p.I463= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV101164292; called by muse, mutect2, varscan2
- PHC1 | c.118C>T p.L40= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs1565512139, COSV101418667, COSV70418003; called by muse, mutect2, varscan2
- PHC1 | c.1956C>T p.V652= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV70418007; called by muse, mutect2, varscan2
- PI4KA | c.5211C>T p.F1737= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV55412288, COSV55424180; called by muse, mutect2, varscan2
- PIMREG | c.333G>A p.L111= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV51470954; called by muse, mutect2, varscan2
- PITPNM1 | c.957C>T p.S319= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV62708369; called by muse, mutect2, varscan2
- PLCB2 | c.30C>T p.P10= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs902250023, COSV53033943; called by muse, mutect2, varscan2
- PLG | c.1977G>A p.L659= | Silent (SNP) | VAF 53/69 reads (77%) | catalogued as COSV57516676; called by muse, mutect2, varscan2
- PM20D1 | c.525G>A p.R175= | Silent (SNP) | VAF 53/96 reads (55%) | catalogued as rs1412699857, COSV65649007, COSV65649483; called by muse, mutect2, varscan2
- POM121L12 | c.234C>T p.I78= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs775680595, COSV101374964, COSV68692532; called by muse, mutect2, varscan2
- POU2F3 | c.510C>T p.L170= | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as COSV52794211; called by muse, mutect2, varscan2
- PPEF2 | c.1455C>T p.I485= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs1224408281, COSV54422795; called by muse, mutect2, varscan2
- PPP1R18 | c.72C>T p.G24= | Silent (SNP) | VAF 99/216 reads (46%) | catalogued as COSV51296530; called by muse, mutect2, varscan2
- PRAME | c.576C>T p.F192= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as rs558928895, COSV67161673; called by muse, mutect2, varscan2
- PREX1 | c.3630C>T p.I1210= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV64248848; called by muse, mutect2, varscan2
- PRMT2 | c.246C>T p.N82= | Silent (SNP) | VAF 58/81 reads (72%) | catalogued as COSV99388467; called by muse, mutect2, varscan2
- PSG1 | c.417C>T p.T139= | Silent (SNP) | VAF 112/197 reads (57%) | catalogued as COSV54948084, COSV54950302; called by muse, mutect2, varscan2
- RAPGEF5 | c.639A>G p.Q213= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV59783972; called by muse, mutect2, varscan2
- REN | c.399G>C p.S133= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV65817824; called by muse, mutect2, varscan2
- RIMKLA | c.789C>T p.I263= | Silent (SNP) | VAF 156/353 reads (44%) | catalogued as COSV68909790; called by muse, mutect2, varscan2
- RING1 | c.342G>A p.R114= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV63002601; called by muse, mutect2, varscan2
- RNF31 | c.747C>T p.S249= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as COSV53760009; called by muse, mutect2, varscan2
- RNPC3 | c.1452G>A p.K484= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV63715431; called by muse, mutect2, varscan2
- RPS19 | c.309C>T p.V103= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1302468356, COSV55743547; called by muse, mutect2
- RYR1 | c.8409G>A p.E2803= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV62098929; called by muse, mutect2, varscan2
- SALL1 | c.3789T>C p.I1263= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV51758388; called by muse, mutect2, varscan2
- SCN11A | c.2871G>A p.T957= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs766452376, COSV56566186; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMG1 | c.441G>A p.G147= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs369069421, COSV99725079; called by muse, mutect2, varscan2
- SLC30A10 | c.798C>T p.P266= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV63071861; called by muse, mutect2, varscan2
- SLC5A10 | c.1716C>T p.F572= (on ENST00000395645 / NM_001042450.4; = p.F588= on NM_152351.5) | Silent (SNP) | VAF 64/110 reads (58%) | catalogued as COSV52413545; called by muse, mutect2, varscan2
- SLCO6A1 | c.1479G>A p.G493= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV65810481; called by muse, mutect2, varscan2
- SMC1A | c.1344C>T p.S448= | Silent (SNP) | VAF 9/9 reads (100%) | catalogued as COSV59129460; called by muse, mutect2, varscan2
- SNRK | c.1680C>T p.F560= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs1396372577, COSV56068349; called by muse, mutect2, varscan2
- SPTB | c.3597C>T p.S1199= | Silent (SNP) | VAF 81/154 reads (53%) | catalogued as rs745505216, COSV67632235; called by muse, mutect2, varscan2
- SPTB | c.249G>A p.R83= | Silent (SNP) | VAF 49/72 reads (68%) | catalogued as COSV67632246; called by muse, mutect2, varscan2
- SRBD1 | c.1725C>T p.F575= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs1342479121, COSV55399325, COSV55401932; called by muse, mutect2, varscan2
- SSX7 | c.132G>A p.E44= | Silent (SNP) | VAF 34/44 reads (77%) | catalogued as rs370804386, COSV53340097; called by muse, mutect2, varscan2
- STAT6 | c.60C>G p.V20= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV55671412, COSV55671684; called by muse, mutect2, varscan2
- SUPT6H | c.765C>T p.P255= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs767236888, COSV58927826; called by muse, mutect2, varscan2
- SYCP1 | c.2745G>A p.R915= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV65697946; called by muse, mutect2, varscan2
- TAFA5 | c.348C>T p.G116= (on ENST00000402357 / NM_001082967.3; = p.G109= on NM_015381.7) | Silent (SNP) | VAF 81/162 reads (50%) | catalogued as rs754818175, COSV60980677; called by muse, mutect2, varscan2
- TENM2 | c.1434C>T p.F478= (on ENST00000518659 / NM_001122679.2; = p.F246= on NM_001080428.3) | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV101317894; called by muse, mutect2, varscan2
- TENM2 | c.2109G>A p.R703= (on ENST00000518659 / NM_001122679.2; = p.R471= on NM_001080428.3) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs760965534, COSV69131605; called by muse, mutect2, varscan2
- TJP3 | c.1866G>A p.V622= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as COSV53661611; called by muse, mutect2, varscan2
- TNFRSF10A | c.1263G>A p.R421= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV55325940; called by muse, mutect2, varscan2
- TOM1 | c.978C>T p.G326= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV101146527; called by muse, mutect2, varscan2
- TP53BP1 | c.1959C>T p.H653= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV99779830; called by muse, mutect2, varscan2
- TRGV8 | c.72G>A p.G24= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as rs973085496; called by muse, mutect2, varscan2
- TRIML1 | c.345C>T p.F115= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs377054198; called by muse, mutect2, varscan2
- TRMT2A | c.1203C>T p.T401= | Silent (SNP) | VAF 55/172 reads (32%) | catalogued as COSV52813659; called by muse, mutect2, varscan2
- TRPC5 | c.678G>A p.E226= | Silent (SNP) | VAF 131/152 reads (86%) | catalogued as COSV53291741; called by muse, mutect2, varscan2
- TRPV2 | c.1128G>T p.L376= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV58428578, COSV58431026; called by muse, mutect2, varscan2
- TSHR | c.1728C>T p.T576= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as COSV53321269; called by muse, mutect2, varscan2
- TSPOAP1 | c.3876G>A p.R1292= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV52109737; called by muse, mutect2, varscan2
- TTC27 | c.604C>T p.L202= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV58652643; called by muse, mutect2, varscan2
33 further variants in this file (0 protein-altering or splice-affecting, 22 silent, 11 other) are not listed here.
